Somatic mutation profile of tumor specimen TCGA-XU-A936-01A (aliquot TCGA-XU-A936-01A-11D-A428-09) from TCGA case TCGA-XU-A936, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymic carcinoma, NOS; Tissue or organ of origin: Thymus; Age at diagnosis: 65.5 years (23,924 days).
Specimen TCGA-XU-A936-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef4fe596-a1bc-4b05-b932-edfa235918da.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-XU-A936-10A (Blood Derived Normal), aliquot TCGA-XU-A936-10A-01D-A42B-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d81cbe57-10fc-4091-b60a-f9ed4aa6ce18

The open-access MAF lists 27 somatic variants for this specimen: 22 protein-altering or splice-affecting, 5 silent.
By variant classification: Missense Mutation 20, Silent 5, Frame Shift Ins 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC158 | c.109A>G p.T37A | Missense Mutation (SNP) | VAF 9/126 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs1218043391; called by muse, mutect2
- CER1 | c.571G>A p.G191R | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.176); catalogued as rs759221042, COSV66603625; called by muse, mutect2, varscan2
- IGF2 | c.350G>A p.R117H (on ENST00000434045 / NM_001127598.3; = p.R61H on NM_000612.6) | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs773449505, COSV56097013; called by muse, mutect2, varscan2
- MAGEB18 | c.567T>A p.S189R | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.36); PolyPhen benign (0.015); catalogued as COSV100305505; called by muse, mutect2
- RAPGEF6 | c.1925G>T p.R642L | Missense Mutation (SNP) | VAF 15/88 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV57249564; called by muse, mutect2, varscan2
- SMARCAD1 | c.2303dup p.N768Kfs*28 | Frame Shift Ins (INS) | VAF 14/76 reads (18%) | catalogued as rs750056186; called by mutect2, varscan2
- SWT1 | c.2252G>A p.R751K | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.978); catalogued as rs914823237; called by muse, mutect2, varscan2
- TAS1R1 | c.1664G>A p.R555H | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs142426315; called by muse, mutect2, varscan2
- TMEM225 | c.215C>T p.S72L | Missense Mutation (SNP) | VAF 23/64 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs773180306, COSV66692942; called by muse, mutect2, varscan2
- VPS13B | c.559C>T p.R187C | Missense Mutation (SNP) | VAF 11/77 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as rs367561688; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ADAM20 | c.1226A>G p.Y409C | Missense Mutation (SNP) | VAF 4/49 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.013); called by muse, mutect2
- AP000721.1 | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 9/53 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.047); called by muse, varscan2
- ASTN1 | c.1391C>T p.A464V | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); called by muse, mutect2
- BSCL2 | c.335T>G p.L112R | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHD3 | c.4864C>T p.P1622S | Missense Mutation (SNP) | VAF 13/43 reads (30%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- DRAM1 | c.487A>T p.I163F | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- FAM155A | c.1306G>A p.A436T | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.025); called by muse, mutect2
- KIDINS220 | c.2917G>A p.E973K | Missense Mutation (SNP) | VAF 3/58 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- PLAAT3 | c.56C>T p.P19L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.66); PolyPhen benign (0.006); called by muse, mutect2
- SIPA1L1 | c.1972C>T p.R658* | Nonsense Mutation (SNP) | VAF 6/50 reads (12%) | called by muse, mutect2
- SUPT6H | c.976G>C p.A326P | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- ZNF614 | c.76G>T p.D26Y | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- ATP6V1A | c.42A>G p.K14= | Silent (SNP) | VAF 58/199 reads (29%) | called by muse, mutect2, varscan2
- OBSCN | c.7036C>T p.L2346= | Silent (SNP) | VAF 5/31 reads (16%) | catalogued as rs1328816295; called by muse, mutect2
- PCDHGA4 | c.2148C>T p.D716= | Silent (SNP) | VAF 6/51 reads (12%) | catalogued as COSV54063087; called by muse, mutect2
- TNXB | c.7866C>T p.H2622= (on ENST00000647633; = p.H2375= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 5/27 reads (19%) | catalogued as rs372616750; called by muse, mutect2, varscan2
- TRIM46 | c.798C>G p.A266= | Silent (SNP) | VAF 16/59 reads (27%) | called by muse, mutect2, varscan2
